Somatic mutation profile of tumor specimen TCGA-W2-A7UY-01A (aliquot TCGA-W2-A7UY-01A-11D-A35I-08) from TCGA case TCGA-W2-A7UY, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 44.7 years (16,335 days).
Specimen TCGA-W2-A7UY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c741a3f6-e8aa-4975-962a-36e049a78327.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W2-A7UY-10A (Blood Derived Normal), aliquot TCGA-W2-A7UY-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/877958a2-f698-4289-84e7-da497a7ad63a

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAP3 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | catalogued as rs1238184307; called by muse, mutect2, varscan2
- ATP8B2 | c.1013G>T p.R338L (on ENST00000672630; = p.R305L on NM_001005855.2) | Missense Mutation (SNP) | VAF 94/223 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV59245873; called by muse, mutect2, varscan2
- CCDC60 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.889); catalogued as rs146647643; called by muse, mutect2, varscan2
- CFH | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121913058, CM044589, CM087105; called by muse, mutect2, varscan2
- CHST15 | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1246429753, COSV60564702; called by muse, mutect2, varscan2
- PAIP1 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs755767615; called by muse, mutect2, varscan2
- SHB | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs749259021, COSV66628568; called by muse, mutect2, varscan2
- TNPO2 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.371); catalogued as COSV63509406; called by muse, varscan2
- ZNF799 | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.981); catalogued as rs1419741296; called by muse, mutect2
- GP2 | c.911T>C p.V304A (on ENST00000381362 / NM_001007240.3; = p.V301A on NM_001502.4) | Missense Mutation (SNP) | VAF 75/200 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HAPLN4 | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- LSM11 | c.926T>A p.V309E | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDYL2 | c.678G>A p.A226= | Silent (SNP) | VAF 48/144 reads (33%) | catalogued as rs531982053, COSV73653970; called by muse, mutect2, varscan2
- CSH2 | c.24C>T p.S8= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as COSV61080176; called by muse, mutect2, varscan2
- MAGEA12 | c.756G>A p.Q252= | Silent (SNP) | VAF 128/178 reads (72%) | called by muse, mutect2, varscan2
- RAD50 | c.2010T>A p.I670= | Silent (SNP) | VAF 54/138 reads (39%) | called by muse, mutect2, varscan2
- TRIP6 | c.690C>T p.V230= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- TXNRD1 | c.978C>T p.Y326= (on ENST00000525566 / NM_001093771.3; = p.Y228= on NM_003330.4) | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- ADGRG6 | c.*37C>T | 3'UTR (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
